Somatic mutation profile of tumor specimen TCGA-61-1913-01A (aliquot TCGA-61-1913-01A-01W-0639-09) from TCGA case TCGA-61-1913, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.1 years (17,575 days).
Specimen TCGA-61-1913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 134b8c5d-9d63-4089-85aa-227ade064a6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1913-11A (Solid Tissue Normal), aliquot TCGA-61-1913-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f62dc0f-bda6-4cad-8748-3f7a38cff67c

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 2, Splice Site 2, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 29/32 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.4070G>A p.C1357Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV55891403; called by muse, mutect2, varscan2
- ANKRD35 | c.2873T>C p.L958P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62911277; called by muse, mutect2, varscan2
- B4GALNT3 | c.1820A>T p.E607V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56756582; called by muse, mutect2, varscan2
- C17orf75 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1017293290; called by muse, mutect2
- C2CD5 | c.1562T>G p.L521* | Nonsense Mutation (SNP) | VAF 76/233 reads (33%) | catalogued as COSV61726705; called by muse, mutect2, varscan2
- CBLL2 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 210/525 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV60369891, COSV60370312; called by muse, mutect2, varscan2
- CD40 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV64848163; called by muse, mutect2, varscan2
- CHRM5 | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs774098229, COSV67248227; called by muse, mutect2, varscan2
- COQ8B | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV54688480; called by muse, mutect2, varscan2
- CST9L | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65408182; called by muse, mutect2, varscan2
- DDAH1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV52306603; called by muse, mutect2, varscan2
- DOCK2 | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV56979180; called by muse, mutect2, varscan2
- DOP1A | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 93/116 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52715502; called by muse, mutect2, varscan2
- FBXO24 | c.1325G>C p.R442P (on ENST00000241071 / NM_033506.3; = p.R480P on NM_012172.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53823765, COSV53828579; called by muse, varscan2
- FLG2 | c.4472C>G p.S1491C | Missense Mutation (SNP) | VAF 323/754 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs774979042, COSV66171635; called by muse, mutect2, varscan2
- GLT1D1 | c.947G>A p.G316E (on ENST00000442111 / NM_001366889.1; = p.G236E on NM_144669.3) | Missense Mutation (SNP) | VAF 130/146 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV55885868; called by muse, mutect2, varscan2
- IARS1 | c.2720G>T p.G907V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV100986733, COSV65112918; called by muse, mutect2, varscan2
- IFTAP | c.48A>C p.L16F | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV57559084; called by muse, mutect2, varscan2
- KRTCAP3 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51995388; called by muse, mutect2, varscan2
- LRP1B | c.785T>G p.I262S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV67258903; called by muse, mutect2, varscan2
- MIA3 | c.1510C>A p.L504I | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.666); catalogued as COSV60516316; called by muse, mutect2, varscan2
- MRPL10 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs762964812, COSV51620933; called by muse, mutect2, varscan2
- MYH14 | c.5987G>C p.*1996Sext*59 | Nonstop Mutation (SNP) | VAF 5/8 reads (63%) | catalogued as COSV51827881; called by muse, mutect2, varscan2
- NRAS | c.96T>G p.Y32* | Nonsense Mutation (SNP) | VAF 107/263 reads (41%) | catalogued as COSV54755771; called by muse, mutect2, varscan2
- NUP43 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100462248; called by muse, mutect2
- PCDHGA4 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53993901; called by muse, mutect2, varscan2
- PODN | c.590A>G p.N197S (on ENST00000395871; = p.N149S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs367579309; called by muse, mutect2, varscan2
- POGLUT3 | c.1498A>C p.K500Q | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV60213687; called by muse, mutect2, varscan2
- TLE3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV58173162; called by muse, mutect2, varscan2
- TLL2 | c.2498A>C p.H833P | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV63574839; called by muse, mutect2, varscan2
- TNPO1 | c.1652A>T p.D551V | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61523387; called by muse, mutect2, varscan2
- TRIO | c.3067-2A>T p.X1023_splice | Splice Site (SNP) | VAF 29/67 reads (43%) | catalogued as COSV60091560; called by muse, mutect2, varscan2
- ZFPM2 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV65875249, COSV65875663; called by muse, mutect2, varscan2
- DNAH11 | c.5779-16_5781del p.X1927_splice | Splice Site (DEL) | VAF 60/87 reads (69%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4458_4478del p.D1487_L1493del | In Frame Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel, varscan2
- SLC11A2 | c.237_250del p.F80Lfs*4 (on ENST00000394904 / NM_001379455.1; = p.F51Lfs*4 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 101/140 reads (72%) | called by mutect2, varscan2
- FAT1 | c.1002C>G p.L334= | Silent (SNP) | VAF 80/351 reads (23%) | catalogued as COSV71675473; called by muse, mutect2, varscan2
- GYS1 | c.66C>T p.F22= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV54404670; called by muse, varscan2
- IARS1 | c.2721A>C p.G907= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100986732; called by muse, mutect2, varscan2
- LGR6 | c.2448G>T p.L816= (on ENST00000367278 / NM_001017403.1; = p.L764= on NM_021636.3) | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV55163942; called by muse, mutect2, varscan2
- NCOA1 | c.2481G>A p.L827= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV56050788; called by muse, mutect2, varscan2
- NEK10 | c.1377T>C p.L459= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as COSV58287936; called by muse, mutect2, varscan2
- NUP210 | c.1830A>C p.V610= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV54411625; called by muse, mutect2, varscan2
- PCSK7 | c.1677C>T p.P559= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54064313; called by muse, mutect2
- PLCL2 | c.1857T>G p.S619= (on ENST00000615277 / NM_001144382.2; = p.S493= on NM_015184.5) | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV67624354; called by muse, mutect2, varscan2
- SLC37A4 | c.882C>A p.S294= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV58156016; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11855A>C | Intron (SNP) | VAF 80/169 reads (47%) | catalogued as COSV100571823; called by muse, mutect2, varscan2
- TIMM50 | c.-4C>G | 5'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as rs1274943459, COSV58680335; called by muse, varscan2
